Somatic mutation profile of tumor specimen MP2PRT-PAVXLT-TMP1-A (aliquot MP2PRT-PAVXLT-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVXLT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,190 days).
Specimen MP2PRT-PAVXLT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe72c591-e705-4483-b74d-2034853022ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXLT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXLT-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42ffabcf-dfa4-4523-890e-b78f26816d85

The open-access MAF lists 76 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 15, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 48/225 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, varscan2
- AL592490.1 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV69427958, COSV69428014; called by muse, mutect2
- ARMCX2 | c.592G>C p.G198R | Missense Mutation (SNP) | VAF 59/925 reads (6%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1489156261; called by muse, mutect2
- CFAP43 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63853191; called by muse, mutect2
- CHL1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1029893346; called by muse, mutect2
- COL9A1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138557524; called by muse, mutect2, varscan2
- CYB5R4 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63750449, COSV63750944; called by muse, mutect2
- DLGAP4 | c.2749G>A p.E917K (on ENST00000339266 / NM_001365621.1; = p.E914K on NM_014902.6) | Missense Mutation (SNP) | VAF 187/454 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs547476479; called by muse, mutect2, varscan2
- EVX2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 58/504 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57964593; called by muse, mutect2, varscan2
- EXOC4 | c.1968G>A p.M656I | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1348657231; called by muse, mutect2
- GRID2 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 94/371 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768214690; called by muse, mutect2, varscan2
- INPPL1 | c.3682C>G p.L1228V | Missense Mutation (SNP) | VAF 21/452 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53359608; called by muse, mutect2
- KCTD21 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 71/445 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.121); catalogued as rs372144983, COSV60741302; called by muse, mutect2, varscan2
- LDB3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 191/472 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs779162531; called by muse, mutect2, varscan2
- MEGF10 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 19/599 reads (3%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); catalogued as COSV99175211; called by muse, mutect2
- MRPS35 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1011830884; called by muse, mutect2
- NLRP6 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 33/520 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs369355458; called by muse, mutect2
- PCLO | c.3428C>T p.S1143L | Missense Mutation (SNP) | VAF 32/439 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61620950; called by muse, mutect2
- PRDM13 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 42/419 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as rs1324630748, COSV65030497; called by muse, mutect2, varscan2
- SDE2 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55253950; called by muse, mutect2
- SLC5A12 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.866); catalogued as rs1007420114; called by muse, mutect2, varscan2
- SOX21 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 49/575 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as COSV65375180; called by muse, mutect2
- STEAP3 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs140512748; called by muse, varscan2
- SYDE2 | c.1544C>G p.S515* | Nonsense Mutation (SNP) | VAF 49/282 reads (17%) | catalogued as rs370879051; called by muse, mutect2, varscan2
- UGDH | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772235942; called by muse, mutect2, varscan2
- WDR49 | c.497C>G p.S166C (on ENST00000308378 / NM_001366158.1; = p.S507C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs533599054; called by muse, mutect2
- ZNF182 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 33/432 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100526950, COSV100527131; called by muse, mutect2
- ZNF257 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV71309326; called by muse, mutect2, varscan2
- ZPLD1 | c.1175C>T p.S392L (on ENST00000466937 / NM_001329788.1; = p.S408L on NM_175056.2) | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.141); catalogued as rs1005218531; called by muse, mutect2
- AKAP11 | c.1505C>G p.S502* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDON | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.4); called by muse, mutect2
- CMTR2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DACT2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); called by muse, mutect2
- DDX43 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2
- DOT1L | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DOT1L | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FOXN4 | c.15C>G p.D5E | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FOXRED2 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FTMT | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GIPC3 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, mutect2
- HIVEP2 | c.3534G>A p.M1178I | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS6L | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); called by muse, mutect2
- KCNH6 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 31/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIF4A | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2
- LCORL | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LCORL | c.1130C>G p.T377R | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAP2 | c.3592C>T p.Q1198* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- PDZD2 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2
- PTAR1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 23/401 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAB11FIP2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RTF1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- SHLD2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- TANK | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2
- TENM1 | c.2521C>G p.L841V | Missense Mutation (SNP) | VAF 108/582 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM252 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 33/410 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- USP26 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 38/649 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ZDHHC13 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF503 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.355); called by muse, mutect2
- ZNF595 | c.916C>A p.H306N | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ABL2 | c.378C>G p.L126= (on ENST00000502732 / NM_007314.4; = p.L111= on NM_005158.5) | Silent (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- CAPN6 | c.13C>T p.L5= | Silent (SNP) | VAF 14/458 reads (3%) | called by muse, mutect2
- CFAP61 | c.1812C>T p.Y604= | Silent (SNP) | VAF 106/265 reads (40%) | catalogued as rs766919114, COSV55638950; called by muse, mutect2, varscan2
- CTNNA2 | c.2404C>T p.L802= | Silent (SNP) | VAF 22/217 reads (10%) | catalogued as COSV58144916; called by muse, mutect2, varscan2
- DOHH | c.519C>T p.F173= | Silent (SNP) | VAF 54/577 reads (9%) | called by muse, mutect2
- DRD5 | c.822C>T p.S274= | Silent (SNP) | VAF 16/400 reads (4%) | catalogued as COSV100431820; called by muse, mutect2
- FOXRED2 | c.1296G>A p.L432= | Silent (SNP) | VAF 52/435 reads (12%) | called by muse, mutect2, varscan2
- LGSN | c.1065C>T p.L355= | Silent (SNP) | VAF 26/484 reads (5%) | catalogued as rs760167561; called by muse, mutect2
- MCOLN2 | c.147C>T p.F49= | Silent (SNP) | VAF 49/399 reads (12%) | catalogued as rs1368651093; called by muse, mutect2, varscan2
- PKD1L2 | c.450C>T p.F150= | Silent (SNP) | VAF 26/432 reads (6%) | called by muse, mutect2
- PSPC1 | c.663C>T p.F221= | Silent (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- TLL2 | c.661C>A p.R221= | Silent (SNP) | VAF 112/286 reads (39%) | catalogued as COSV63575694; called by muse, varscan2
- YAE1 | c.186C>T p.F62= | Silent (SNP) | VAF 94/312 reads (30%) | called by muse, mutect2, varscan2
- YTHDF3 | c.453T>C p.Y151= | Silent (SNP) | VAF 25/366 reads (7%) | catalogued as rs1349449494; called by muse, mutect2
- ZNF777 | c.2427G>A p.T809= | Silent (SNP) | VAF 41/551 reads (7%) | catalogued as rs1355835735; called by muse, mutect2
- RPGR | c.2520+553G>C | Intron (SNP) | VAF 32/382 reads (8%) | called by muse, mutect2
